Gene-level copy-number profile of tumor specimen AP-9UHJ-SQ from APOLLO case AP-9UHJ, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3.
Specimen AP-9UHJ-SQ: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d97d7a4-72ea-4819-bf00-e0e3c09e53e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-9UHJ-N9 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,761 have no estimate.
https://portal.gdc.cancer.gov/files/601af0ef-7598-4096-a4a0-016a61e264d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 696; copy number 1: 15,225; copy number 2: 29,808; copy number 3: 9,480; copy number 4: 3,242; copy number 5: 369; copy number 6: 31; copy number 7: 9; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 352 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr1:3,454,665–3,796,498, 17 genes: ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1.
- chr1:12,773,738–13,617,957, 43 genes: PRAMEF12, PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1, BRWD1P1, PDPN.
- chr1:17,189,783–18,859,682, 22 genes (within-gene range 0–1): LINC02783, AL590644.2, PADI1, PADI3, MIR3972, PADI4, PADI6, RCC2-AS1, RCC2, ARHGEF10L, LINC02810, ACTL8, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1, KLHDC7A, DYNLL1P3, AL031737.1, PAX7, TAS1R2.
- chr1:29,329,620–30,421,108, 9 genes: LINC01756, AL671862.1, AC092265.1, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:83,003,412–83,003,517, 1 gene (within-gene range 0–1): RNU6-615P.
- chr4:187,970,273–188,350,024, 9 genes: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1.
- chr7:132,086,266–132,087,992, 1 gene: AC105443.1.
- chr11:134,671,426–135,075,908, 7 genes: AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr12:129,839,928–129,854,944, 2 genes (within-gene range 0–1): AC055717.3, AC055717.1.
- chr13:18,467,172–18,551,214, 3 genes: ZNF962P, BNIP3P7, LINC00349.
- chr13:100,027,769–100,088,950, 3 genes: NDUFA12P1, PCCA-DT, ASNSP3.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,945,389, 42 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1.
- chr19:5,158,495–5,578,349, 7 genes: PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4.
- chr22:16,572,027–17,258,235, 46 genes (within-gene range 0–1): AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP.
- chr22:22,409,766–22,679,345, 26 genes: IGLV1-40, ASH2LP1, IGLVI-38, IGLV5-37, IGLV1-36, AC245291.2, IGLV7-35, AC245291.1, ZNF280B, ZNF280A, PRAME, LL22NC03-63E9.3, IGLV2-34, IGLV2-33, IGLV3-32, IGLV3-31, IGLV3-30, BCRP4, AC244250.4, POM121L1P, GGTLC2, IGLV3-29, IGLV2-28, IGLV3-27, IGLV3-26, IGLVVI-25-1.
- chr22:43,923,792–44,862,788, 23 genes: PNPLA3, SAMM50, RPL35AP36, PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8.
- chr22:47,259,366–50,445,090, 64 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 411 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,391,313–234,980,804, 19 genes, copy number 5: TARBP1, LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr1:248,436,359–248,655,528, 17 genes, copy number 5: OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr1:248,810,446–248,937,043, 8 genes, copy number 5: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr5:50,396,192–50,603,511, 2 genes, copy number 8: EMB, AC112187.2.
- chr5:55,838,801–56,111,329, 8 genes, copy number 5 (within-gene range 2–5): HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1.
- chr5:64,165,843–65,123,474, 12 genes, copy number 6–7: RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA.
- chr5:66,507,380–67,806,600, 15 genes, copy number 5 (within-gene range 3–5): LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3.
- chr7:91,311,368–91,515,427, 1 gene, copy number 5 (within-gene range 3–5): AC079760.2.
- chr7:91,380,778–94,066,661, 49 genes, copy number 5–6: AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1.
- chr7:97,885,868–98,401,090, 20 genes, copy number 5: SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26.
- chr7:98,794,718–101,321,823, 145 genes, copy number 5 (broad region; genes not listed).
- chr7:101,815,904–103,514,007, 64 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:103,484,208–103,484,539, 1 gene, copy number 5 (within-gene range 2–5): RN7SKP86.
- chr10:88,785,600–88,877,544, 4 genes, copy number 5: RCBTB2P1, LIPM, ANKRD22, PTCD2P2.
- chr12:22,063,773–22,437,041, 1 gene, copy number 5 (within-gene range 2–5): ST8SIA1.
- chr12:22,116,629–22,690,665, 10 genes, copy number 5: SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr18:59,267,035–60,902,726, 35 genes, copy number 5: RAX, CPLX4, LMAN1, AC016229.2, CCBE1, AC016229.1, AC090213.1, AC010776.1, AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1, AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31.

Autosomal genes at a single copy (total copy number 1): 12,881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
